Somatic mutation profile of tumor specimen TCGA-MH-A857-01A (aliquot TCGA-MH-A857-01A-11D-A34Z-10) from TCGA case TCGA-MH-A857, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.3 years (23,114 days).
Specimen TCGA-MH-A857-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95580313-9c73-4330-82b9-20945e8aec98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A857-10A (Blood Derived Normal), aliquot TCGA-MH-A857-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffd60417-f258-4e89-b23a-8ae221eccc87

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, In Frame Del 2, Intron 2, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.7280T>A p.L2427Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1085307113, COSV63869220, COSV63869886, COSV63874900; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B3GNT2 | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.797); catalogued as COSV100114043; called by muse, mutect2, varscan2
- C2CD5 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100448472; called by muse, mutect2, varscan2
- CDSN | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs370680006; called by muse, mutect2, varscan2
- CGNL1 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777396993, COSV55573660; called by muse, mutect2, varscan2
- ECEL1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.878); catalogued as COSV100458454; called by muse, mutect2
- EML5 | c.4157G>A p.G1386D (on ENST00000380664; = p.G1394D on NM_183387.3) | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100715053; called by muse, mutect2
- GPR162 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99163694; called by muse, mutect2
- LYST | c.11191G>T p.V3731L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101088253; called by muse, mutect2, varscan2
- MAG | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.508); catalogued as rs1389837167, COSV100727613; called by muse, mutect2, varscan2
- PCDHA10 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 50/123 reads (41%) | catalogued as COSV100247731, COSV56486136; called by muse, mutect2, varscan2
- PIWIL4 | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV100133064; called by muse, mutect2, varscan2
- PTPRR | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV99316314; called by muse, mutect2, varscan2
- RNF17 | c.3477T>G p.F1159L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99692026, COSV99692247; called by muse, mutect2, varscan2
- SCAF1 | c.2483C>A p.S828Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV100862052; called by muse, mutect2, varscan2
- TXNIP | c.498_500del p.K167del | In Frame Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs782691020; called by mutect2, pindel, varscan2
- CRY2 | c.1473_1475del p.H492del | In Frame Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- EFHB | c.1289-9_1289del p.X430_splice | Splice Site (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- KMT2A | c.10405del p.Q3469Sfs*19 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- NCOA6 | c.4979_4980del p.F1660Yfs*56 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- EPG5 | c.945A>G p.T315= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as rs746594600, COSV99956534; called by muse, mutect2, varscan2
- MROH1 | c.4215C>T p.L1405= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- NPC1L1 | c.2682C>T p.F894= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs267601517, COSV56923846; called by muse, mutect2, varscan2
- SEMA3E | c.666G>A p.L222= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs1311045860, COSV57091938; called by muse, mutect2, varscan2
- ST3GAL6 | c.927G>T p.V309= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV99504512; called by muse, mutect2, varscan2
- AC005863.1 | n.177C>A | RNA (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- ATAT1 | c.107+218T>C | Intron (SNP) | VAF 26/66 reads (39%) | catalogued as COSV52541228; called by muse, mutect2, varscan2
- OBSCN | c.18662-2817_18662-2807del | Intron (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
